Somatic mutation profile of tumor specimen TCGA-QR-A70G-01B (aliquot TCGA-QR-A70G-01B-11D-A35D-08) from TCGA case TCGA-QR-A70G, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 54.5 years (19,914 days).
Specimen TCGA-QR-A70G-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 692a6fa8-5883-4a76-becf-c33bf6afef5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70G-10A (Blood Derived Normal), aliquot TCGA-QR-A70G-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/524170cf-9aa7-4fcb-86bf-1869b4f3ec9c

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, 3'Flank 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGFBP3 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51872419; called by muse, mutect2
- NPY1R | c.914G>C p.C305S | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56715361; called by muse, mutect2, varscan2
- PER2 | c.55G>T p.V19L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54523260; called by muse, mutect2
- CCDC88C | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EGFR | c.198_224del p.E66_Y74del | In Frame Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel
- FNDC7 | c.1146G>T p.L382F | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GABRA2 | c.1218A>C p.E406D | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KCNH5 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2, varscan2
- MACROD2 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MMP14 | c.558T>A p.H186Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCR1 | c.655C>T p.L219F | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- POLE2 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BICRAL | c.2823G>T p.R941= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SLC22A2 | c.1557G>A p.G519= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV65269504; called by muse, mutect2, varscan2
- TTN | c.16368C>T p.D5456= (on ENST00000591111; = p.D4529= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs760724229, COSV60304073; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701206 G>A | 3'Flank (SNP) | VAF 20/127 reads (16%) | catalogued as rs201392732; called by muse, mutect2, varscan2
